Somatic mutation profile of tumor specimen TCGA-CV-7100-01A (aliquot TCGA-CV-7100-01A-11D-2012-08) from TCGA case TCGA-CV-7100, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.2 years (24,183 days).
Specimen TCGA-CV-7100-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2ade739-1021-45bb-bf32-6bd1bccf0f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7100-10A (Blood Derived Normal), aliquot TCGA-CV-7100-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6a0828b-1af6-4357-8647-045ec4e95194

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Frame Shift Ins 4, Silent 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK3 | c.1417del p.Q473Sfs*30 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs769139957; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 34/59 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV99860370; called by muse, mutect2, varscan2
- ARSI | c.1643G>T p.C548F | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.124); catalogued as COSV100155892; called by muse, mutect2, varscan2
- CGB5 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as rs1040033779, COSV56823853; called by mutect2, varscan2
- FSTL5 | c.1885dup p.I629Nfs*2 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as rs766244516; called by mutect2, pindel, varscan2
- GPBP1L1 | c.869dup p.S291Efs*15 | Frame Shift Ins (INS) | VAF 19/76 reads (25%) | catalogued as rs1557695006; called by mutect2, pindel, varscan2
- NAALADL2 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69157760; called by muse, mutect2, varscan2
- PRAMEF10 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1174936313; called by muse, varscan2
- SLC30A8 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs767594541, COSV69973671; called by muse, mutect2, varscan2
- SLC4A4 | c.1361C>G p.A454G (on ENST00000264485 / NM_001098484.3; = p.A410G on NM_003759.4) | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV99138986; called by muse, mutect2, varscan2
- ALK | c.2791_2793delinsA p.G931Rfs*16 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by pindel, varscan2*
- IL34 | c.632_636dup p.Y213Sfs*20 | Frame Shift Ins (INS) | VAF 27/124 reads (22%) | called by mutect2, pindel, varscan2
- TIMMDC1 | c.322_323dup p.S108Rfs*40 | Frame Shift Ins (INS) | VAF 35/102 reads (34%) | called by mutect2, pindel, varscan2
- KPNA4 | c.885C>T p.H295= | Silent (SNP) | VAF 59/145 reads (41%) | catalogued as COSV100515012; called by muse, mutect2, varscan2
- PLCB1 | c.1060C>T p.L354= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs563074402, COSV100569432; called by muse, mutect2, varscan2
- UBR4 | c.9480A>C p.L3160= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100920253; called by muse, mutect2, varscan2
